Somatic mutation profile of tumor specimen TCGA-CC-5260-01A (aliquot TCGA-CC-5260-01A-01D-A12Z-10) from TCGA case TCGA-CC-5260, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIC; Tumor grade: G1; Age at diagnosis: 61.2 years (22,345 days).
Specimen TCGA-CC-5260-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed5af777-2598-4b3f-9d4d-fffc1da372ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-5260-10B (Blood Derived Normal), aliquot TCGA-CC-5260-10B-01D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f6efbb7-4192-4ded-a317-f3ad417194e1

The open-access MAF lists 65 somatic variants for this specimen: 46 protein-altering or splice-affecting, 12 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 12, 5'UTR 4, Frame Shift Del 3, Splice Site 2, 3'UTR 2, Frame Shift Ins 1, In Frame Del 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 74/252 reads (29%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCG5 | c.711A>C p.E237D | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.411); catalogued as COSV53210801; called by muse, mutect2, varscan2
- ADAMTS10 | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs377333794; called by muse, mutect2, varscan2
- ADAMTS7 | c.2438G>A p.G813D | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66307239; called by muse, mutect2, varscan2
- AP000812.4 | c.631C>A p.L211M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.985); catalogued as COSV56191918; called by muse, mutect2, varscan2
- CDH1 | c.1936+1G>A p.X646_splice | Splice Site (SNP) | VAF 15/77 reads (19%) | catalogued as COSV55730906, COSV55731485; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4208G>A p.R1403Q | Missense Mutation (SNP) | VAF 28/256 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767034315, COSV62574308; called by muse, mutect2, varscan2
- CFAP36 | c.1013_1015del p.E338del | In Frame Del (DEL) | VAF 49/222 reads (22%) | catalogued as rs528334905; called by pindel, varscan2
- CHRNA1 | c.227T>A p.L76Q | Missense Mutation (SNP) | VAF 70/223 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53682870; called by muse, mutect2, varscan2
- DCDC1 | c.3506A>G p.Y1169C (on ENST00000597505 / NM_001367979.1; = p.Y276C on NM_020869.3) | Missense Mutation (SNP) | VAF 76/272 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV60306421; called by muse, mutect2, varscan2
- DIPK2A | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 65/239 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59857298; called by muse, mutect2, varscan2
- FAM53C | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs769884886, COSV53511578; called by muse, mutect2, varscan2
- GPR82 | c.453T>A p.F151L | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56887364; called by muse, mutect2, varscan2
- GYPA | c.254A>T p.H85L | Missense Mutation (SNP) | VAF 79/344 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV51626330; called by muse, mutect2, varscan2
- HTR6 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs200009000; called by muse, mutect2, varscan2
- KANK1 | c.3478G>A p.G1160S | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs374492770; called by muse, mutect2, varscan2
- KLRG2 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as rs138023732; called by muse, mutect2
- KMT5B | c.103A>T p.T35S | Missense Mutation (SNP) | VAF 113/430 reads (26%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV58566055; called by muse, mutect2, varscan2
- KPRP | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as rs1428244418, COSV64221363; called by muse, mutect2, varscan2
- KRTAP10-11 | c.275C>G p.S92C | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV58177845; called by muse, mutect2
- MACF1 | c.18618G>T p.E6206D (on ENST00000372915; = p.E4251D on NM_012090.5) | Missense Mutation (SNP) | VAF 35/111 reads (32%) | catalogued as COSV57121032; called by muse, mutect2, varscan2
- MAPKAP1 | c.1294A>G p.I432V (on ENST00000265960 / NM_001006617.3; = p.I396V on NM_024117.3) | Missense Mutation (SNP) | VAF 32/402 reads (8%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.817); catalogued as rs766806809, COSV56367907; called by muse, mutect2
- MMP16 | c.571G>A p.G191S | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54165113; called by muse, mutect2, varscan2
- MUC17 | c.5102C>T p.P1701L | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs751201961, COSV60281009; called by muse, varscan2
- MYB | c.221C>T p.T74I | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100214445; called by muse, varscan2
- NLGN4X | c.1040A>G p.D347G | Missense Mutation (SNP) | VAF 155/499 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52017791; called by muse, mutect2, varscan2
- OR8H2 | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 33/279 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs767833447, COSV57944558; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.2390G>A p.G797E (on ENST00000259318 / NM_001136562.3; = p.G1028E on NM_007203.5) | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs777197311, COSV52176289; called by mutect2, varscan2
- PCDH15 | c.2047C>T p.R683C | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs573043647, COSV57311329, COSV57330716; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRMT8 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as rs867638529, COSV54214160; called by muse, mutect2, varscan2
- RAB11FIP1 | c.137A>T p.Q46L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54760102, COSV99043929; called by muse, mutect2, varscan2
- RAB27B | c.485C>A p.T162K | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV50494836; called by muse, mutect2, varscan2
- RIC8A | c.1531C>T p.Q511* (on ENST00000526104 / NM_001286134.1; = p.Q517* on NM_021932.5) | Nonsense Mutation (SNP) | VAF 10/130 reads (8%) | catalogued as COSV57342747; called by muse, mutect2
- SEMA5B | c.3371C>T p.T1124M | Missense Mutation (SNP) | VAF 209/634 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as rs369693926; called by muse, mutect2, varscan2
- SGCA | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs371675217, CM163140, CM951149, COSV56249347; called by muse, mutect2, varscan2
- SLC4A8 | c.1409A>C p.Y470S | Missense Mutation (SNP) | VAF 46/501 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV60652322; called by muse, mutect2
- SMC1A | c.3257A>T p.K1086M | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59129261; called by muse, mutect2, varscan2
- STXBP3 | c.1280T>A p.I427N | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as COSV64182200; called by muse, mutect2, varscan2
- TMPRSS7 | c.2255C>T p.A752V (on ENST00000452346; = p.A626V on NM_001042575.2) | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759865349, COSV69980647; called by muse, mutect2, varscan2
- TNKS | c.3741-2A>T p.X1247_splice | Splice Site (SNP) | VAF 19/35 reads (54%) | catalogued as COSV60057577; called by muse, mutect2, varscan2
- ZNF518B | c.1852T>A p.L618I | Missense Mutation (SNP) | VAF 74/272 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV58722635; called by muse, mutect2, varscan2
- BAP1 | c.1705del p.V569Cfs*2 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | called by mutect2, pindel, varscan2
- MAPKBP1 | c.1973del p.Q658Rfs*52 (on ENST00000456763 / NM_001128608.2; = p.Q652Rfs*52 on NM_014994.3) | Frame Shift Del (DEL) | VAF 38/182 reads (21%) | called by mutect2, pindel
- SLC16A2 | c.11A>T p.Q4L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); called by muse, varscan2
- TCEANC2 | c.52_53insT p.K18Ifs*14 | Frame Shift Ins (INS) | VAF 36/144 reads (25%) | called by mutect2, pindel, varscan2
- USP37 | c.62del p.K21Sfs*10 | Frame Shift Del (DEL) | VAF 70/281 reads (25%) | called by mutect2, pindel, varscan2
- AL592490.1 | c.645G>A p.S215= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV69426263; called by muse, mutect2, varscan2
- CD1E | c.708C>T p.Y236= | Silent (SNP) | VAF 16/300 reads (5%) | catalogued as COSV63771009; called by muse, mutect2
- CMKLR1 | c.267C>T p.N89= (on ENST00000312143 / NM_001142344.2; = p.N87= on NM_004072.3) | Silent (SNP) | VAF 34/111 reads (31%) | catalogued as rs201022995, COSV100379629; called by muse, mutect2, varscan2
- FBXO10 | c.2286G>A p.V762= | Silent (SNP) | VAF 26/310 reads (8%) | catalogued as COSV52832950; called by muse, mutect2
- MKI67 | c.9012A>T p.G3004= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as COSV64074327; called by muse, mutect2, varscan2
- PICALM | c.1011T>C p.A337= | Silent (SNP) | VAF 151/544 reads (28%) | catalogued as COSV62670775; called by muse, mutect2, varscan2
- PRAMEF17 | c.747A>T p.V249= | Silent (SNP) | VAF 109/303 reads (36%) | called by muse, mutect2, varscan2
- PRKAA2 | c.663G>A p.T221= | Silent (SNP) | VAF 34/586 reads (6%) | catalogued as rs1193150275, COSV64803756; called by muse, mutect2
- SIPA1L3 | c.2812C>T p.L938= | Silent (SNP) | VAF 32/74 reads (43%) | catalogued as COSV55914180; called by muse, mutect2, varscan2
- TMC1 | c.402T>A p.L134= | Silent (SNP) | VAF 62/254 reads (24%) | catalogued as COSV52775352; called by muse, mutect2, varscan2
- TMEM260 | c.696C>G p.P232= | Silent (SNP) | VAF 121/569 reads (21%) | catalogued as rs1040465640, COSV55099182; called by muse, mutect2, varscan2
- ZFC3H1 | c.12A>T p.A4= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV57348593; called by muse, mutect2, varscan2
- DRD1 | c.-375A>T | 5'UTR (SNP) | VAF 134/377 reads (36%) | catalogued as COSV101192351; called by muse, mutect2, varscan2
- GK | c.*45A>T | 3'UTR (SNP) | VAF 42/163 reads (26%) | catalogued as COSV100970731; called by muse, mutect2, varscan2
- IRF2BPL | c.-579T>C | 5'UTR (SNP) | VAF 18/46 reads (39%) | catalogued as rs1472713735, COSV99467625; called by muse, varscan2
- ORC3 | c.-24G>A | 5'UTR (SNP) | VAF 32/62 reads (52%) | catalogued as COSV57641161; called by muse, mutect2, varscan2
- RAG1 | c.*386del | 3'UTR (DEL) | VAF 4/37 reads (11%) | catalogued as rs886048258; ClinVar: uncertain significance; called by pindel, varscan2
- S1PR3 | c.-148+2443C>A | Intron (SNP) | VAF 18/70 reads (26%) | catalogued as COSV100560729; called by muse, mutect2, varscan2
- TWIST1 | c.-242C>A | 5'UTR (SNP) | VAF 20/106 reads (19%) | catalogued as COSV99642936, COSV99643054; called by muse, mutect2, varscan2
